CPTAC case C3L-01465 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/c02e2a7b-1ce1-4827-ba77-807e087e3797

Demographics
Sex at birth: male; Race: white; Year of birth: 1949; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 67.4 years (24,603 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T4; AJCC pathologic N: N0; AJCC pathologic M: MX; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: RX; Last known disease status: Tumor free; Days to last known disease status: 1,393 days (3.8 years); Progression or recurrence: no; Days to last follow up: 1,393 days (3.8 years); Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10.7 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 11; Margin status: Uninvolved; Sarcomatoid present: No.
   Immunotherapy (Including Vaccines) — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (5 entries)
- Days to follow up: 350 days; Disease response: With Tumor; Karnofsky performance status: 100; ECOG performance status: 0.
- Days to follow up: 664 days (1.8 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,037 days (2.8 years); Disease response: Progressive Disease; Progression or recurrence: Yes; Days to recurrence: 49 days; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,037 days (2.8 years); Disease response: With Tumor; Karnofsky performance status: 90; ECOG performance status: 1.
- Days to follow up: 1,393 days (3.8 years); Disease response: Tumor Free; Karnofsky performance status: 100; ECOG performance status: 0.

Other clinical attributes
- Weight: 68.04 kg; Height: 167.64 cm; BMI: 24.21.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01465-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 220 mg; Time between excision and freezing: 14 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01465-21: Section location: Tumor invades the upper and middle poles; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-01465-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-01465-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen.
